Somatic mutation profile of tumor specimen TCGA-AA-A01T-01A (aliquot TCGA-AA-A01T-01A-21W-A096-10) from TCGA case TCGA-AA-A01T, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage III; Age at diagnosis: 63.5 years (23,192 days).
Specimen TCGA-AA-A01T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e340be2e-a3c5-4d50-b188-b0a2be0dbe9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01T-11A (Solid Tissue Normal), aliquot TCGA-AA-A01T-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8496167f-31ca-4267-84d5-c7254333dca1

The open-access MAF lists 100 somatic variants for this specimen: 76 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 21, Nonsense Mutation 5, Splice Site 2, Intron 2, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 60/77 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1574+1G>C p.X525_splice (on ENST00000380548 / NM_001040272.6; = p.S525= on NM_052866.5) | Splice Site (SNP) | VAF 35/225 reads (16%) | catalogued as rs756185107, COSV99444738; called by muse, mutect2, varscan2
- ANK2 | c.10673A>T p.H3558L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100004155; called by muse, mutect2, varscan2
- ANKRD33 | c.7G>A p.A3T (on ENST00000340970 / NM_001304459.2; = p.A138T on NM_182608.4) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs145080334; called by muse, mutect2, varscan2
- AP2A1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1444804311, COSV100756510; called by muse, mutect2, varscan2
- APOL5 | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV104374368, COSV99968464; called by muse, mutect2
- AR | c.1886-1G>T p.X629_splice | Splice Site (SNP) | VAF 25/221 reads (11%) | catalogued as CS024559, COSV65954104, COSV65957130; called by muse, mutect2, varscan2
- BRDT | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100740355; called by muse, mutect2, varscan2
- C10orf71 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs772395613, COSV60505696; called by muse, mutect2, varscan2
- C11orf65 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 213/917 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as COSV67597070; called by muse, mutect2, varscan2
- C8B | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100980908; called by muse, varscan2
- CCNA2 | c.620C>G p.T207S | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV99145093; called by muse, mutect2, varscan2
- CEP70 | c.1389T>A p.F463L | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV53874716; called by muse, mutect2, varscan2
- CEP78 | c.1123G>A p.E375K (on ENST00000424347 / NM_001349840.2; = p.E376K on NM_032171.3) | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as rs1451630903, COSV99450358, COSV99450909; called by muse, mutect2, varscan2
- CHST10 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 323/412 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs756646964, COSV51805383; called by muse, mutect2, varscan2
- CNOT1 | c.4060C>A p.Q1354K | Missense Mutation (SNP) | VAF 174/1030 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55314334; called by muse, mutect2, varscan2
- CPXCR1 | c.233A>T p.K78I | Missense Mutation (SNP) | VAF 136/213 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV99342414; called by muse, mutect2, varscan2
- DMD | c.5183G>A p.R1728H | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs780599147, COSV63741495; called by muse, mutect2
- DNAJB5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV56624917, COSV56625584; called by muse, mutect2, varscan2
- DNM3 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 160/661 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100798635; called by muse, mutect2, varscan2
- DYTN | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV65970553; called by muse, mutect2, varscan2
- FASTKD3 | c.819C>G p.H273Q | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99242100; called by muse, mutect2, varscan2
- FBXO22 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 224/928 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1171779016, COSV57616708; called by muse, mutect2, varscan2
- FREM2 | c.9126G>T p.K3042N | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99750715; called by muse, mutect2, varscan2
- FRMD4B | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 294/584 reads (50%) | catalogued as rs775396961, COSV101273416, COSV68329261; called by muse, mutect2, varscan2
- HCN4 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 82/114 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370442588, COSV99983260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR4 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 188/437 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as rs201201172; called by muse, mutect2, varscan2
- IKBKB | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV60596269; called by muse, mutect2, varscan2
- IL32 | c.511G>A p.G171R (on ENST00000396890 / NM_001308078.4; = p.G125R on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs538977484, COSV50403905; called by muse, mutect2
- IRX6 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99306803; called by muse, mutect2, varscan2
- JAG1 | c.3374C>A p.P1125H | Missense Mutation (SNP) | VAF 121/781 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV99653520; called by muse, mutect2, varscan2
- KATNIP | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV55175826; called by muse, mutect2
- KCNV2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as rs759192531, COSV66055692; called by muse, mutect2, varscan2
- LAS1L | c.2198T>C p.L733P | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100162036; called by muse, varscan2
- LRP2 | c.12902G>A p.G4301E | Missense Mutation (SNP) | VAF 187/245 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55577254, COSV99788647; called by muse, mutect2, varscan2
- MARK4 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488814; called by muse, mutect2, varscan2
- MORC3 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101265050; called by muse, mutect2, varscan2
- MS4A7 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs752512120, COSV55729076; called by muse, mutect2, varscan2
- MYH2 | c.1514A>C p.K505T | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99820938; called by muse, mutect2, varscan2
- MYO1A | c.2833G>A p.V945I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs748970956, COSV55652541; called by muse, mutect2, varscan2
- NAGK | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 86/480 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs1239954045, COSV54903143; called by muse, mutect2, varscan2
- NCOA5 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV99276020; called by muse, mutect2
- NIP7 | c.10T>G p.L4V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54741985; called by muse, mutect2, varscan2
- NPR1 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100902079; called by muse, mutect2, varscan2
- NRK | c.584_585insG p.D195Efs*12 | Frame Shift Ins (INS) | VAF 96/703 reads (14%) | catalogued as COSV99689128; called by mutect2, pindel, varscan2
- OR4S2 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs201389134, COSV56746202; called by muse, mutect2, varscan2
- PCDHA7 | c.1999G>T p.V667L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.052); catalogued as COSV100971020; called by muse, varscan2
- PCDHB7 | c.950T>C p.L317S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV50801311, COSV99177356; called by muse, mutect2, varscan2
- PCLO | c.10345G>A p.D3449N | Missense Mutation (SNP) | VAF 99/599 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1263883799, COSV61622742; called by muse, mutect2, varscan2
- PSD2 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.347); catalogued as rs764750179, COSV51200807; called by muse, mutect2, varscan2
- PUM2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57578762; called by muse, mutect2, varscan2
- SGCD | c.842G>T p.C281F (on ENST00000435422 / NM_001128209.2; = p.C282F on NM_000337.5) | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61905693; called by muse, mutect2, varscan2
- SLC22A16 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57928203; called by muse, mutect2, varscan2
- SLC2A13 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV55113195; called by muse, mutect2, varscan2
- SLC7A5 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200265403; called by muse, mutect2, varscan2
- SLC9C2 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs770432941, COSV100877005; called by muse, mutect2, varscan2
- SNAP47 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.536); catalogued as rs770833379, COSV100248480; called by muse, mutect2, varscan2
- SNX13 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 97/666 reads (15%) | catalogued as COSV68065668; called by muse, mutect2, varscan2
- SPTBN2 | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV100020454; called by muse, mutect2, varscan2
- STAB2 | c.5374G>T p.A1792S | Missense Mutation (SNP) | VAF 180/781 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1188056736, COSV101186293; called by muse, mutect2, varscan2
- TBX19 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); catalogued as rs148791684; called by muse, mutect2, varscan2
- TMEM132D | c.1213T>C p.Y405H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101399221, COSV101399536; called by muse, mutect2, varscan2
- TMEM218 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV54444898; called by muse, mutect2, varscan2
- TNRC6B | c.1510T>C p.S504P | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV57291209; called by muse, mutect2, varscan2
- TRIML1 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.387); catalogued as rs147254109; called by muse, mutect2, varscan2
- TSGA10 | c.1779G>C p.Q593H | Missense Mutation (SNP) | VAF 175/487 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100747799; called by muse, mutect2, varscan2
- TSTD2 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs370389075, COSV52245680; called by muse, mutect2, varscan2
- UNC13A | c.2380G>A p.V794M | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1234944404, COSV53190867; called by muse, mutect2, varscan2
- UNC5C | c.1350A>C p.R450S | Missense Mutation (SNP) | VAF 226/604 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as COSV101498025; called by muse, varscan2
- VARS1 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65154922; called by muse, mutect2
- WNT7A | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs774758917, COSV53200773; called by muse, mutect2, varscan2
- ZCCHC24 | c.675C>G p.H225Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV64886379; called by muse, mutect2, varscan2
- APC | c.715del p.A239Qfs*54 | Frame Shift Del (DEL) | VAF 51/242 reads (21%) | called by mutect2, pindel, varscan2
- ASAP1 | c.2818_2838del p.P940_L946del | In Frame Del (DEL) | VAF 47/116 reads (41%) | called by mutect2, pindel, varscan2
- ZNF140 | c.823_824insCT p.C275Sfs*217 | Frame Shift Ins (INS) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- CABS1 | c.450C>T p.D150= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs1444000814, COSV99909203; called by muse, mutect2, varscan2
- CD101 | c.1371C>T p.P457= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs139644223, COSV99868991; called by muse, mutect2, varscan2
- FAM187B | c.645C>T p.Y215= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs13382163, COSV61201050; called by muse, mutect2, varscan2
- GDF10 | c.852G>A p.A284= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs782612950; called by muse, varscan2
- H2BC7 | c.102C>T p.R34= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs368844614, COSV61911668; called by muse, mutect2, varscan2
- JAKMIP3 | c.597C>A p.R199= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV53821190; called by muse, varscan2
- KLHL1 | c.801C>G p.V267= | Silent (SNP) | VAF 41/281 reads (15%) | catalogued as COSV100917867, COSV64768603, COSV64777932; called by muse, varscan2
- LPAR6 | c.1032C>T p.A344= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs772128045, COSV57300130; called by muse, mutect2, varscan2
- MYH3 | c.3720G>A p.S1240= | Silent (SNP) | VAF 79/99 reads (80%) | catalogued as rs377201866; called by muse, mutect2, varscan2
- OR7G3 | c.450C>T p.I150= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs529517536, COSV59640067; called by muse, mutect2, varscan2
- PKHD1 | c.3861G>A p.V1287= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs1262409248, COSV61860592; called by muse, mutect2, varscan2
- SHC3 | c.1638C>G p.L546= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV101011876, COSV65437202; called by muse, mutect2, varscan2
- SLC12A5 | c.276C>T p.T92= (on ENST00000454036 / NM_001134771.2; = p.T69= on NM_020708.5) | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV54790276, COSV54792893; called by muse, mutect2, varscan2
- SLC17A7 | c.1566C>T p.S522= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1226185492, COSV55546937; called by muse, mutect2, varscan2
- SYNE2 | c.13020T>C p.D4340= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV59943410; called by muse, mutect2, varscan2
- TBC1D5 | c.967C>T p.L323= | Silent (SNP) | VAF 27/457 reads (6%) | catalogued as COSV99511851; called by muse, mutect2
- THEM5 | c.420G>A p.S140= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs762789735, COSV64312774; called by muse, mutect2, varscan2
- TNC | c.237G>A p.P79= | Silent (SNP) | VAF 64/117 reads (55%) | catalogued as rs149512169; called by muse, mutect2, varscan2
- TTN | c.42391C>A p.R14131= (on ENST00000591111; = p.R6707= on NM_003319.4) | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV59939652, COSV60005623; called by muse, mutect2, varscan2
- ZFHX4 | c.9930G>T p.L3310= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs374859191; called by muse, mutect2, varscan2
- ZNF286A | c.360G>A p.K120= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as COSV67845253; called by muse, mutect2, varscan2
- DCHS2 | n.3719G>A | RNA (SNP) | VAF 142/695 reads (20%) | catalogued as COSV61769297; called by muse, mutect2, varscan2
- MAGEC3 | c.1728+42A>T | Intron (SNP) | VAF 39/225 reads (17%) | catalogued as COSV100026107, COSV68924295; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+697C>A | Intron (SNP) | VAF 159/210 reads (76%) | catalogued as COSV53349623, COSV99526674; called by muse, mutect2, varscan2
